Gene-level copy-number profile of tumor specimen SM-JU32X from CPTAC case C1230738, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Tumor grade: G4.
Specimen SM-JU32X: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92536111-b913-48be-98a5-c09a73b35ca7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105281 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/ec2a6ade-888d-4442-8f6f-d8d7403b793c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 6; copy number 2: 2,599; copy number 3: 17,152; copy number 4: 31,005; copy number 5: 6,013; copy number 6: 1,437; copy number 7: 48; copy number 8: 40; copy number 9: 42; copy number 11: 1; copy number 58: 4; copy number 59: 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr9:21,802,636–23,438,700, 20 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:23,632,106–23,632,360, 1 gene: SUMO2P2.
- chr10:87,591,607–88,259,372, 15 genes: AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr22:18,715,815–18,757,906, 2 genes: PPP1R26P4, FAM230E.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 48 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,590,960–52,659,301, 1 gene, copy number 59: USP46.
- chr4:54,229,280–54,446,723, 4 genes, copy number 58 (within-gene range 4–58): PDGFRA, LINC02283, AC098587.1, AC098868.1.
- chr14:65,124,352–66,509,394, 23 genes, copy number 9 (within-gene range 4–9): RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708, FUT8, FUT8-AS1, RPL21P8, MIR625, EIF1AXP2, NCOA4P1, FTH1P13, AL391261.1, AL391261.2, YBX1P1, LINC02290, Y_RNA, AL359232.1, AL157997.1, CCDC196.
- chr14:76,958,098–77,271,312, 19 genes, copy number 9: AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A.
- chr17:46,372,855–46,487,141, 1 gene, copy number 11: NSFP1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
